MMRF case MMRF_2168 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/0165ada0-f393-4ffb-8f80-6d87f830584d

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 50 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 50.9 years (18,590 days); ISS stage: I; Days to last known disease status: 877 days (2.4 years); Days to last follow up: 877 days (2.4 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 281 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 322 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 135 days; Days to treatment end: 276 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 288 days; Days to treatment end: 288 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 308 days; Days to treatment end: 308 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 309 days; Days to treatment end: 309 days.
   Treatment given: Therapeutic agents: Dexamethasone + Ixazomib + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 430 days (1.2 years); Days to treatment end: 542 days (1.5 years).
   Treatment given: Therapeutic agents: Daratumumab; Regimen or line of therapy: First line of therapy; Days to treatment start: 626 days (1.7 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -39 (ECOG 0): M Protein 1.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.93 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.826 mg/dL; Immunoglobulin G 10.4 g/L; Immunoglobulin A 18.6 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 1.6 µg/mL; Lactate Dehydrogenase 2.9 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 293 ×10⁹/L; Creatinine 99 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.48 mmol/L; Albumin 47 g/L; Total Protein 8 g/dL; Glucose 7.26 mmol/L.
- Day 49 (ECOG 0): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.887 mg/dL; Immunoglobulin G 7.37 g/L; Immunoglobulin A 11.4 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 2.53 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 299 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.38 mmol/L; Albumin 43 g/L; Total Protein 7.4 g/dL; Glucose 7.37 mmol/L.
- Day 134 (ECOG 0): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.31 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.904 mg/dL; Immunoglobulin G 6.41 g/L; Immunoglobulin A 9.23 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 2.82 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 283 ×10⁹/L; Creatinine 107 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Total Protein 6.8 g/dL; Glucose 9.24 mmol/L.
- Day 232 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.35 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.3 mg/dL; Immunoglobulin G 6.97 g/L; Immunoglobulin A 6.07 g/L; Immunoglobulin M 0.31 g/L; Hemoglobin 7.32 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 280 ×10⁹/L; Creatinine 109 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.23 mmol/L; Glucose 9.13 mmol/L.
- Day 329 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.2 mg/dL; Immunoglobulin G 6.42 g/L; Immunoglobulin A 4.25 g/L; Immunoglobulin M 0.24 g/L; Lactate Dehydrogenase 3.92 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 323 ×10⁹/L; Creatinine 108 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 6.3 g/dL; Glucose 8.97 mmol/L.
- Day 408 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.11 mg/dL; Hemoglobin 6.82 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 307 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.48 mmol/L; Albumin 43 g/L; Total Protein 7.6 g/dL; Glucose 6.55 mmol/L.
- Day 511 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.54 mg/dL; Lactate Dehydrogenase 3.32 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 14.4 mmol/L.
- Day 605 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.06 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 4.89 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 1.4 µg/mL; Lactate Dehydrogenase 3.2 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 275 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.55 mmol/L; Albumin 47 g/L; Total Protein 7.3 g/dL; Glucose 6.27 mmol/L.
- Day 696 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.661 mg/dL; Immunoglobulin G 6.42 g/L; Immunoglobulin A 2.4 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 1.9 µg/mL; Hemoglobin 7.32 mmol/L; Leukocytes 4.4 ×10⁹/L; Platelets 283 ×10⁹/L; Creatinine 118 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.45 mmol/L; Albumin 40 g/L; Total Protein 6.4 g/dL; Glucose 7.32 mmol/L.
- Day 780 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.26 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.701 mg/dL; Beta 2 Microglobulin 2 µg/mL; Hemoglobin 6.94 mmol/L; Leukocytes 5.4 ×10⁹/L; Platelets 353 ×10⁹/L; Creatinine 113 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 6.1 g/dL; Glucose 8.47 mmol/L.
- Day 877 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.603 mg/dL; Beta 2 Microglobulin 1.6 µg/mL; Lactate Dehydrogenase 3.75 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 518 ×10⁹/L; Creatinine 102 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.48 mmol/L; Albumin 43 g/L; Total Protein 6.2 g/dL; Glucose 11.6 mmol/L.

Other clinical attributes
- Day -39: Weight: 112 kg; Height: 182 cm.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples)
- Sample MMRF_2168_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -39 days.
- Sample MMRF_2168_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -39 days.
- Sample MMRF_2168_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 605 days (1.7 years).
